Somatic mutation profile of tumor specimen MMRF_2087_2_BM_CD138pos (aliquot MMRF_2087_2_BM_CD138pos_T1_KHS5U_L11011) from MMRF case MMRF_2087, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 74.4 years (27,166 days).
Specimen MMRF_2087_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 00684adf-a8c7-4c80-abf9-32328fa04de4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2087_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2087_1_PB_Whole_C2_KHS5U_L08670; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9abf67ae-cbe2-4691-9e6c-a11b4244fd39

The open-access MAF lists 90 somatic variants for this specimen: 35 protein-altering or splice-affecting, 16 silent, 39 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, 3'UTR 18, Silent 16, Intron 8, 3'Flank 4, 5'Flank 3, 5'UTR 3, RNA 3, Nonsense Mutation 2, Splice Site 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADNP | c.3221G>A p.G1074E | Missense Mutation (SNP) | VAF 103/208 reads (50%) | SIFT tolerated, low confidence (0.26); PolyPhen probably damaging (0.998); catalogued as COSV62426826; called by muse, mutect2, varscan2
- AGRN | c.6100G>A p.V2034I | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs760232764, COSV65070299; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARFGEF3 | c.3283C>T p.R1095W | Missense Mutation (SNP) | VAF 37/66 reads (56%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.857); catalogued as rs952834056, COSV52457413; called by muse, mutect2, varscan2
- CA7 | c.110C>G p.S37C | Missense Mutation (SNP) | VAF 100/225 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.719); catalogued as COSV58156581; called by muse, mutect2, varscan2
- CASZ1 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs760076051; called by muse, mutect2, varscan2
- DOP1A | c.4904C>T p.T1635I | Missense Mutation (SNP) | VAF 97/229 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as COSV99382264; called by muse, mutect2, varscan2
- IGHV5-51 | c.306G>C p.W102C | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1555541175; called by muse, mutect2, varscan2
- IGLV2-14 | c.130A>T p.T44S | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.053); catalogued as rs555320226; called by muse, varscan2
- KCNH5 | c.1055T>C p.L352P | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100525024; called by muse, mutect2, varscan2
- RPS5 | c.163C>T p.R55W | Missense Mutation (SNP) | VAF 74/238 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.274); catalogued as COSV52190978; called by muse, mutect2, varscan2
- RRP12 | c.428C>T p.T143M | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs559101512, COSV100212964; called by muse, mutect2, varscan2
- SH3BP4 | c.2731C>T p.R911W | Missense Mutation (SNP) | VAF 81/151 reads (54%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs779250344; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2150C>G p.P717R | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ARG1 | c.666-1G>A p.X222_splice | Splice Site (SNP) | VAF 55/131 reads (42%) | called by muse, mutect2, varscan2
- ATG16L2 | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 22/189 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- CERS2 | c.1138G>A p.D380N | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- CHD7 | c.4481G>A p.R1494Q | Missense Mutation (SNP) | VAF 8/161 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- CRLF1 | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- DOCK2 | c.3614T>G p.V1205G | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); called by muse, mutect2
- DSCAM | c.789G>T p.M263I | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by muse, mutect2
- ERAP2 | c.970+3A>G | Splice Region (SNP) | VAF 41/126 reads (33%) | called by muse, mutect2, varscan2
- GSE1 | c.3226C>T p.P1076S | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- HSD17B3 | c.515T>C p.M172T | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IGKV1-33 | c.104C>G p.A35G | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.489); called by muse, varscan2
- IGLV2-14 | c.94T>C p.S32P | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.612); called by muse, varscan2
- LAMB4 | c.2836+2T>A p.X946_splice | Splice Site (SNP) | VAF 64/246 reads (26%) | called by muse, mutect2, varscan2
- MFHAS1 | c.2735G>T p.G912V | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- PLIN5 | c.1183C>A p.L395M | Missense Mutation (SNP) | VAF 19/193 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- PTPRG | c.3370G>T p.E1124* | Nonsense Mutation (SNP) | VAF 80/291 reads (27%) | called by muse, mutect2, varscan2
- RHOBTB2 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 35/287 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC25A4 | c.158G>A p.G53E | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- STMND1 | c.349G>T p.V117F | Missense Mutation (SNP) | VAF 70/139 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- UBR4 | c.8231C>G p.S2744* | Nonsense Mutation (SNP) | VAF 49/140 reads (35%) | called by muse, mutect2, varscan2
- UXT | c.247G>A p.V83I | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.306); called by muse, mutect2
- ZP3 | c.218T>G p.L73W (on ENST00000394857 / NM_001110354.2; = p.L22W on NM_007155.6) | Missense Mutation (SNP) | VAF 61/221 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCC8 | c.3504G>A p.L1168= | Silent (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
- ADAMTS10 | c.3171C>T p.C1057= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as COSV54357644; called by muse, mutect2, varscan2
- ATP4A | c.1719G>A p.E573= | Silent (SNP) | VAF 43/269 reads (16%) | catalogued as COSV52867440; called by muse, mutect2, varscan2
- DBH | c.609C>T p.P203= | Silent (SNP) | VAF 38/183 reads (21%) | catalogued as rs542369046; called by muse, mutect2
- DDX19A | c.1230C>T p.P410= | Silent (SNP) | VAF 58/153 reads (38%) | catalogued as rs1379100097; called by muse, varscan2
- IL33 | c.525C>T p.D175= | Silent (SNP) | VAF 88/201 reads (44%) | catalogued as rs780716485, COSV67342725; called by muse, mutect2, varscan2
- OR2T8 | c.165G>A p.T55= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as rs562352417, COSV60662094, COSV60664997; called by muse, mutect2
- PRXL2C | c.387G>A p.L129= | Silent (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2
- RPL37A | c.93C>T p.I31= | Silent (SNP) | VAF 96/244 reads (39%) | catalogued as rs1478055639; called by muse, varscan2
- SCAF4 | c.1893A>G p.K631= | Silent (SNP) | VAF 46/115 reads (40%) | called by muse, mutect2, varscan2
- SHOX | c.831C>T p.A277= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as rs1341478838; called by muse, mutect2, varscan2
- SLC26A11 | c.390C>T p.S130= | Silent (SNP) | VAF 20/149 reads (13%) | catalogued as rs376502934; called by muse, mutect2, varscan2
- SORT1 | c.2112C>T p.Y704= | Silent (SNP) | VAF 15/21 reads (71%) | catalogued as rs529657236; called by muse, mutect2, varscan2
- TRMT5 | c.1152T>C p.V384= | Silent (SNP) | VAF 88/215 reads (41%) | called by muse, mutect2, varscan2
- UCKL1 | c.885C>T p.H295= | Silent (SNP) | VAF 27/48 reads (56%) | catalogued as rs1019718698; called by muse, mutect2, varscan2
- ZNF292 | c.2919A>C p.P973= | Silent (SNP) | VAF 69/184 reads (38%) | called by muse, mutect2, varscan2
- AFDN | chr6:167970560 C>T | 3'Flank (SNP) | VAF 12/81 reads (15%) | called by muse, mutect2, varscan2
- ATP2B4 | c.*132_*167del | 3'UTR (DEL) | VAF 12/41 reads (29%) | called by mutect2, pindel
- BCL11B | c.*4071T>A | 3'UTR (SNP) | VAF 27/75 reads (36%) | called by muse, mutect2, varscan2
- C12orf77 | n.331T>C | RNA (SNP) | VAF 107/265 reads (40%) | catalogued as rs372039444; called by muse, mutect2, varscan2
- CACNA2D1 | chr7:81948307 C>T | 3'Flank (SNP) | VAF 35/141 reads (25%) | called by muse, mutect2, varscan2
- CAMKMT | c.*184C>T | 3'UTR (SNP) | VAF 28/68 reads (41%) | catalogued as rs947825894; called by muse, mutect2, varscan2
- CCDC102B | c.*1043T>C | 3'UTR (SNP) | VAF 7/88 reads (8%) | called by muse, mutect2
- CDH12 | c.*349C>T | 3'UTR (SNP) | VAF 13/67 reads (19%) | catalogued as rs1267401908; called by muse, mutect2, varscan2
- CILP | c.*266C>T | 3'UTR (SNP) | VAF 22/134 reads (16%) | called by muse, mutect2, varscan2
- CST9 | c.*125C>T | 3'UTR (SNP) | VAF 19/42 reads (45%) | called by muse, mutect2, varscan2
- CYP3A43 | c.433-114T>A | Intron (SNP) | VAF 18/83 reads (22%) | called by muse, mutect2, varscan2
- CYTIP | c.-38A>G | 5'UTR (SNP) | VAF 10/47 reads (21%) | called by muse, mutect2, varscan2
- DOCK4 | c.3402-521C>T | Intron (SNP) | VAF 36/351 reads (10%) | catalogued as rs550095248, COSV69854604; called by muse, mutect2, varscan2
- ELL2 | c.-72C>T | 5'UTR (SNP) | VAF 7/49 reads (14%) | called by muse, mutect2, varscan2
- FAM163A | c.*1784T>G | 3'UTR (SNP) | VAF 9/178 reads (5%) | called by muse, mutect2
- FGL2 | c.*2473T>G | 3'UTR (SNP) | VAF 15/92 reads (16%) | called by muse, mutect2, varscan2
- FLNC | c.5299-151C>T | Intron (SNP) | VAF 10/31 reads (32%) | called by muse, mutect2, varscan2
- FUT7 | chr9:137035873 del C | 5'Flank (DEL) | VAF 39/232 reads (17%) | called by mutect2, pindel, varscan2
- GAREM1 | c.*4256T>A | 3'UTR (SNP) | VAF 40/141 reads (28%) | called by muse, mutect2, varscan2
- H4-16 | chr12:14775342 G>A | 5'Flank (SNP) | VAF 61/154 reads (40%) | called by muse, mutect2, varscan2
- LINC00615 | n.284G>A | RNA (SNP) | VAF 27/67 reads (40%) | called by muse, mutect2, varscan2
- LRRTM4 | c.*21T>A | 3'UTR (SNP) | VAF 9/30 reads (30%) | called by muse, mutect2, varscan2
- MAN2B2 | c.2815-655G>T | Intron (SNP) | VAF 18/153 reads (12%) | called by muse, mutect2, varscan2
- MEF2A | c.*1434C>A | 3'UTR (SNP) | VAF 8/134 reads (6%) | called by muse, mutect2
- MTPAP | c.*372A>C | 3'UTR (SNP) | VAF 28/79 reads (35%) | called by muse, mutect2, varscan2
- NAMPTP1 | n.765A>G | RNA (SNP) | VAF 34/260 reads (13%) | called by muse, mutect2
- NINJ1 | c.304+35C>G | Intron (SNP) | VAF 11/358 reads (3%) | called by muse, mutect2
- NRXN3 | c.-573G>C | 5'UTR (SNP) | VAF 60/125 reads (48%) | called by muse, mutect2, varscan2
- PAQR9 | chr3:142950067 T>G | 3'Flank (SNP) | VAF 8/30 reads (27%) | called by muse, mutect2
- PDGFA | c.*216G>A | 3'UTR (SNP) | VAF 13/75 reads (17%) | called by muse, mutect2, varscan2
- PIFO | c.*763G>T | 3'UTR (SNP) | VAF 22/29 reads (76%) | called by muse, mutect2, varscan2
- PLXNA4 | c.1372-86960del | Intron (DEL) | VAF 183/372 reads (49%) | catalogued as COSV58124083; called by mutect2, pindel, varscan2
- SLC9A4 | c.*23T>C | 3'UTR (SNP) | VAF 74/150 reads (49%) | called by muse, mutect2, varscan2
- SUCO | c.3266-79T>G | Intron (SNP) | VAF 14/38 reads (37%) | called by muse, mutect2, varscan2
- TECRL | chr4:64275634 A>G | 3'Flank (SNP) | VAF 57/130 reads (44%) | called by muse, mutect2, varscan2
- TEX19 | c.*1020T>C | 3'UTR (SNP) | VAF 51/105 reads (49%) | catalogued as rs745745394; called by muse, mutect2, varscan2
- VSTM4 | c.457+5078C>T | Intron (SNP) | VAF 18/43 reads (42%) | called by muse, mutect2, varscan2
- ZBTB37 | chr1:173865325 del GGATTTCTAAAA | 5'Flank (DEL) | VAF 5/30 reads (17%) | called by mutect2, pindel, varscan2
- ZSWIM2 | c.*67del | 3'UTR (DEL) | VAF 18/39 reads (46%) | called by mutect2, pindel, varscan2
